Somatic mutation profile of tumor specimen MP2PRT-PAPHLN-TMP1-A (aliquot MP2PRT-PAPHLN-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPHLN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.9 years (3,238 days).
Specimen MP2PRT-PAPHLN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58d448df-ae2b-4b59-ae02-1477ae02378b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHLN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHLN-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5ec44be-1023-414f-9e08-ef4c0597fede

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCND3 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 234/501 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100136591, COSV100136850; called by muse, mutect2, varscan2
- LTB4R2 | c.793G>T p.G265C (on ENST00000528054; = p.G234C on NM_019839.5) | Missense Mutation (SNP) | VAF 316/781 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as rs775172650; called by muse, mutect2, varscan2
- ACVRL1 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- ERG | c.1232dup p.E412Gfs*61 (on ENST00000398919 / NM_001243428.1; = p.E388Gfs*61 on NM_004449.4) | Frame Shift Ins (INS) | VAF 206/607 reads (34%) | called by pindel, varscan2
- PROX2 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 180/392 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, varscan2
- RIT1 | c.245_246insGCC p.F82delinsLP | In Frame Ins (INS) | VAF 67/174 reads (39%) | called by mutect2, pindel, varscan2
- CDH12 | c.1548T>C p.D516= | Silent (SNP) | VAF 95/210 reads (45%) | called by muse, mutect2, varscan2
- NUP210 | c.5631A>G p.S1877= | Silent (SNP) | VAF 183/366 reads (50%) | catalogued as rs755299672, COSV99596930; called by muse, mutect2, varscan2
- TAS2R1 | c.192C>T p.Y64= | Silent (SNP) | VAF 97/217 reads (45%) | catalogued as rs139834398, COSV101225837; called by muse, mutect2, varscan2
